Somatic mutation profile of tumor specimen TCGA-S9-A6U1-01A (aliquot TCGA-S9-A6U1-01A-21D-A33T-08) from TCGA case TCGA-S9-A6U1, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 22.6 years (8,271 days).
Specimen TCGA-S9-A6U1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b63d9e3b-1441-4454-9efe-267769def1ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6U1-10A (Blood Derived Normal), aliquot TCGA-S9-A6U1-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d381e96-7f52-465a-8ba5-44f5803bb41d

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 10, Silent 8, Frame Shift Del 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 71/207 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC33 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs374632000; called by muse, mutect2
- DSG1 | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1429340018, COSV99936592; called by muse, mutect2
- FCGBP | c.5785G>A p.A1929T | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as rs1273367609; called by muse, mutect2, varscan2
- INTS4 | c.1816C>G p.Q606E | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV101417286; called by muse, mutect2, varscan2
- MS4A1 | c.538A>C p.T180P | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.473); catalogued as COSV100619434; called by muse, mutect2
- OR4F6 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 15/543 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV100187000; called by muse, mutect2
- PCDH19 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs1444535055, COSV55263509, COSV99720811; called by muse, mutect2, varscan2
- PRDM9 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1412435381, COSV57001698, COSV57015025; called by muse, mutect2, varscan2
- SEL1L2 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569791808, COSV99533949; called by muse, mutect2
- SLC22A6 | c.1569G>A p.W523* | Nonsense Mutation (SNP) | VAF 9/244 reads (4%) | catalogued as COSV100842934; called by muse, mutect2
- AC024940.1 | n.3313G>A | Splice Region (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- ATRX | c.3268_3271del p.E1090Rfs*27 | Frame Shift Del (DEL) | VAF 199/611 reads (33%) | called by mutect2, pindel, varscan2
- XKR3 | c.1005del p.I335Mfs*19 | Frame Shift Del (DEL) | VAF 89/309 reads (29%) | called by mutect2, pindel, varscan2
- CMA1 | c.622C>T p.L208= | Silent (SNP) | VAF 9/173 reads (5%) | catalogued as COSV99157250, COSV99157753; called by muse, mutect2
- HYDIN | c.9786C>T p.A3262= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101158468; called by mutect2, varscan2
- PLEKHA6 | c.2130G>T p.V710= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99692802; called by muse, mutect2, varscan2
- ROBO2 | c.396A>G p.R132= | Silent (SNP) | VAF 23/329 reads (7%) | catalogued as COSV100170042; called by muse, mutect2
- SEC23IP | c.957C>T p.Y319= | Silent (SNP) | VAF 63/191 reads (33%) | catalogued as rs1034305253, COSV100957114; called by muse, mutect2, varscan2
- SSTR1 | c.594C>G p.T198= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV99943162; called by muse, mutect2
- TIMELESS | c.2811G>A p.V937= | Silent (SNP) | VAF 15/296 reads (5%) | catalogued as rs765615967, COSV99974337; called by muse, mutect2
- USP48 | c.2472G>A p.V824= | Silent (SNP) | VAF 70/192 reads (36%) | catalogued as COSV100380264; called by muse, mutect2, varscan2
